TCGA case TCGA-CM-4750 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c777a777-373a-4773-9566-6c373261f00a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 34.2 years (12,478 days); Year of diagnosis: 2010; AJCC pathologic T: T1; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 244 days.
   Pathology details: Circumferential resection margin: 4; Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 52; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 210 days; Number of cycles: 11; Treatment dose: 41,450 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 210 days; Number of cycles: 12; Treatment dose: 6,950 mg; Route of administration: Intravesical.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 210 days; Number of cycles: 12; Treatment dose: 5,690 mg/day; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 168 days; Number of cycles: 9; Treatment dose: 1,075 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 244 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 1 ng/mL.
- MLH1 (IHC): Loss of Expression.
- MSH2 (IHC): Loss of Expression.
- MSH6 (IHC): Loss of Expression.
- PMS2 (IHC): Loss of Expression.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 84.5 kg; Height: 173 cm; BMI: 28.2.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-4750-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.6; Shortest dimension: 0.4.
  Slide TCGA-CM-4750-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 10; Percent stromal cells: 15.
  Slide TCGA-CM-4750-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 15.
- Sample TCGA-CM-4750-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-4750-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Colon; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 1; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Not Expressed; Mismatch rep proteins loss IHC: MSH2-Not Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Not Expressed.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4, Route of administrations: Route of administration: Intravesical.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 244 days; disease-specific survival: no event (censored), 244 days; disease-free interval: no event (censored), 244 days; progression-free interval: no event (censored), 244 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CM-4750-01A-01D-1406-01): tumor purity 0.67, ploidy 3.51, whole-genome doublings 1.
